Gene-level copy-number profile of tumor specimen TCGA-A7-A6VV-01A from TCGA case TCGA-A7-A6VV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.2 years (18,695 days).
Specimen TCGA-A7-A6VV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.7406aaff-b28a-4b4c-8fa3-b4e208b8cf85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A6VV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83bf8ccc-b9cd-4461-82f1-4bfabab63c55

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 3,749; copy number 2: 25,241; copy number 3: 17,280; copy number 4: 8,996; copy number 5: 2,654; copy number 6: 1,055; copy number 7: 252; copy number 8: 296; copy number 9: 11; copy number 10: 100; copy number 11: 73; copy number 13: 3; copy number 14: 14; copy number 15: 17; copy number 22: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A6VV-01A-22D-A33D-01): tumor purity 0.53, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:160,849,313–161,050,546, 3 genes: AC096656.1, RN7SL423P, AC009313.1.
- chr2:205,253,304–205,253,503, 1 gene: AC008171.1.
- chr3:64,174,401–64,200,965, 2 genes: PRDX3P4, PRICKLE2-AS3.
- chr4:90,682,996–90,839,037, 2 genes: AC093729.1, TMSB4XP8.
- chr5:95,964,999–96,215,519, 4 genes (within-gene range 0–2): AC008592.2, FABP5P5, MIR583HG, MIR583.
- chr5:156,019,228–156,039,977, 1 gene: AC011351.1.
- chr10:67,334,123–67,403,410, 2 genes: RPL7AP51, MIR7151.
- chr10:78,943,328–79,067,895, 2 genes (within-gene range 0–4): ZMIZ1-AS1, AL356753.1.
- chr10:87,751,512–87,863,533, 4 genes (within-gene range 0–2): ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene: AC063965.2.
- chr11:16,484,084–16,484,671, 1 gene: AKR1B1P3.
- chr11:86,431,590–86,622,867, 1 gene (within-gene range 0–2): AP001831.1.
- chr11:86,441,108–86,765,467, 3 genes (within-gene range 0–2): ME3, AP003059.1, AP003059.2.
- chr11:86,821,143–86,857,947, 4 genes: MOB4P2, OR7E13P, AP000654.1, OR7E2P.
- chr12:11,649,674–11,895,377, 1 gene (within-gene range 0–5): ETV6.
- chr12:75,600,047–75,698,816, 5 genes: AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1.
- chr12:99,647,753–99,985,619, 2 genes: FAM71C, AC078916.1.
- chr14:68,113,706–68,236,539, 4 genes: AL133370.2, AL133370.1, RN7SL706P, RN7SL108P.
- chr16:6,703,883–6,874,005, 4 genes: AC007012.2, AC007012.1, RNU7-99P, RNU6-457P.
- chr17:60,851,382–61,135,969, 6 genes: HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74, AC005856.1.
- chr18:34,493,290–34,891,844, 3 genes (within-gene range 0–2): DTNA, AC013290.1, AC022601.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,487 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–163,769,691, 886 genes, copy number 5–6 (broad region; genes not listed).
- chr1:164,555,584–169,104,907, 108 genes, copy number 5–10 (broad region; genes not listed).
- chr2:107,254,691–108,534,196, 27 genes, copy number 8 (within-gene range 4–8): LINC01789, AC096669.1, LINC01885, LINC01886, AC064869.1, GACAT1, RGPD4-AS1, RGPD4, AC009963.2, AC009963.1, RPL22P8, SRSF3P5, SLC5A7, LINC01593, ACTP1, LINC01594, SETD6P1, SULT1C3, WASF1P1, SULT1C2, SULT1C2P2, SULT1C2P1, GMCL1P2, SULT1C4, SMIM12P1, GCC2, GCC2-AS1.
- chr3:89,107,621–91,513,775, 10 genes, copy number 6: EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr4:41,113,942–42,402,487, 26 genes, copy number 5–7: RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3.
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).
- chr6:137,823,673–138,422,197, 13 genes, copy number 6: WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2.
- chr6:138,435,213–138,464,383, 2 genes, copy number 6: MIR3145, AL391669.1.
- chr8:46,028,804–139,463,016, 1,325 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr9:470,291–746,106, 1 gene, copy number 10 (within-gene range 2–10): KANK1.
- chr9:659,986–5,856,426, 86 genes, copy number 6–10 (broad region; genes not listed).
- chr10:43,741,437–46,373,563, 67 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:20,043,846–21,575,686, 16 genes, copy number 5 (within-gene range 2–5): NAV2-AS2, NAV2-AS1, AC068860.1, DBX1, HTATIP2, PRMT3, HMGB1P40, AC090707.2, SLC6A5, NELL1, AC090707.1, RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337.
- chr11:30,830,369–39,261,213, 124 genes, copy number 6–22 (within-gene range 0–22) (broad region; genes not listed).
- chr12:12,049,844–12,211,084, 3 genes, copy number 5 (within-gene range 3–5): BCL2L14, PTMAP9, MIR1244-4.
- chr12:12,155,262–12,155,772, 1 gene, copy number 5: AC007537.1.
- chr12:41,658,676–44,503,596, 48 genes, copy number 6–7: RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2.
- chr12:57,797,376–57,959,148, 11 genes, copy number 6 (within-gene range 2–6): AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr14:41,514,972–49,753,150, 91 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr14:49,861,176–64,338,112, 293 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr16:9,753,404–10,182,928, 1 gene, copy number 8 (within-gene range 1–8): GRIN2A.
- chr16:10,033,684–12,574,287, 77 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr16:12,842,487–13,563,388, 7 genes, copy number 6: AC092324.1, RPL35AP34, SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1.
- chr16:87,057,784–90,222,851, 130 genes, copy number 5 (broad region; genes not listed).
- chr19:33,283,978–33,773,509, 13 genes, copy number 5: AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8.
- chr20:16,177,933–16,259,603, 2 genes, copy number 5 (within-gene range 4–5): AL161941.1, PPIAP17.
- chr21:10,328,411–34,784,886, 409 genes, copy number 7–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,338. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
